Gene-level copy-number profile of tumor specimen ALCH-B34M-TTP1-A from ALCHEMIST case ALCH-B34M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.3 years (23,472 days).
Specimen ALCH-B34M-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d3e43da-f283-4f3c-b644-dc38d37a6cc0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34M-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/f639ebdd-221c-4530-968f-6061b3b3359b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 5,702; copy number 2: 51,736; copy number 3: 809; copy number 4: 83; copy number 6: 1; copy number 7: 8; copy number 8: 12; copy number 10: 1; copy number 36: 2.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,189,953, 1 gene: PIGPP2.
- chr1:62,208,136–62,211,666, 2 genes (within-gene range 0–1): AL162739.1, Y_RNA.
- chr4:128,069,014–128,069,612, 1 gene (within-gene range 0–2): AC099340.1.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr4:165,053,864–165,060,554, 1 gene: TRIM75P.
- chr5:181,099,140–181,100,666, 1 gene: FOXO1B.
- chr5:181,222,499–181,235,808, 3 genes (within-gene range 0–1): TRIM41, MIR4638, AC008443.1.
- chr6:107,133,071–107,133,170, 1 gene: RNU6-1299P.
- chr7:55,731,100–55,739,605, 3 genes: Metazoa_SRP, SUMO2P3, CICP11.
- chr7:105,530,209–105,567,677, 2 genes (within-gene range 0–1): AC073073.1, RINT1.
- chr7:152,402,780–152,402,893, 1 gene (within-gene range 0–2): Y_RNA.
- chr9:124,262,876–124,265,809, 1 gene (within-gene range 0–1): AL162724.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:119,093,140–119,165,714, 3 genes: AL355598.2, DENND10, SFXN4.
- chr15:50,417,385–50,418,692, 1 gene: AHCYP7.
- chr16:12,881,170–12,881,493, 1 gene: RPL35AP34.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–2): AC092143.1, AC092143.2, TUBB3.
- chr19:56,127,236–56,127,466, 1 gene: AC024580.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 6: AC113430.1.
- chr5:181,306,502–181,342,213, 3 genes, copy number 8: AC138035.1, AC138035.3, AC138035.2.
- chr13:112,313,467–112,321,758, 1 gene, copy number 8: LINC01043.
- chr14:105,583,731–105,588,395, 1 gene, copy number 7: IGHA2.
- chr16:1,256,059–1,259,008, 2 genes, copy number 7: TPSD1, AC120498.2.
- chr16:1,273,751–1,276,522, 1 gene, copy number 10: AC120498.7.
- chr16:32,649,193–32,788,944, 13 genes, copy number 7–8: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:46,571,537–46,575,094, 2 genes, copy number 36: AC092368.2, AC092368.1.

Autosomal genes at a single copy (total copy number 1): 3,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
